Somatic mutation profile of tumor specimen BA2908D (aliquot aq-BA2908D) from BEATAML1.0 case 2516, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Primary diagnosis: Acute myeloid leukemia without maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.2 years (23,816 days).
Specimen BA2908D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 839ccf5a-1d9d-44e7-9268-ea2b8f8efdff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2531D (Solid Tissue Normal), aliquot aq-BA2531D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a61404a-d78e-4eb5-9409-37b74888bd75

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 12, Silent 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT3A | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 17/47 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs147001633, COSV53036153, COSV53040144, COSV53040431; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- IDH2 | c.515G>A p.R172K | Missense Mutation (SNP) | VAF 86/198 reads (43%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs121913503, COSV57468734, COSV57468971, COSV57472976; ClinVar: pathogenic / not provided / likely pathogenic; called by muse, varscan2
- ADGRB3 | c.4240-1G>A p.X1414_splice | Splice Site (SNP) | VAF 59/127 reads (46%) | catalogued as COSV53234296, COSV53247825; called by muse, mutect2, varscan2
- DNAH9 | c.11818G>A p.V3940M | Missense Mutation (SNP) | VAF 62/146 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.098); catalogued as rs1422056708; called by muse, mutect2, varscan2
- PADI2 | c.1051G>T p.D351Y | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64945498; called by muse, mutect2, varscan2
- SORCS2 | c.1181C>T p.T394M | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs373750171, COSV100211807, COSV61180215; called by muse, mutect2
- THSD4 | c.2615C>T p.T872M | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as rs760643657, COSV55980864; called by muse, mutect2, varscan2
- B3GLCT | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 151/334 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- CHN1 | c.260G>T p.R87I | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- CYTH1 | c.540C>G p.F180L | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- ITGA3 | c.1270C>A p.L424M | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.525); called by muse, mutect2
- NEO1 | c.1331A>G p.D444G | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- OTUD7B | c.2345C>T p.P782L | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ASMTL | c.1176G>A p.E392= | Silent (SNP) | VAF 84/171 reads (49%) | called by muse, mutect2, varscan2
- EIF2S3B | c.423G>A p.L141= | Silent (SNP) | VAF 52/124 reads (42%) | called by muse, mutect2, varscan2
- NCOA3 | c.3381T>C p.H1127= | Silent (SNP) | VAF 106/239 reads (44%) | called by muse, mutect2, varscan2
